CCDI case PBCBDU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/10263410-0d0e-49ea-b71d-3a6512a9d9b2

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Gastrointestinal stromal tumor, NOS: ICD-O-3 morphology code: 8936/1; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 23.1 years (8,446 days).

Biospecimens (2 samples)
- Sample 0DR7Y7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DR7YC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
